Somatic mutation profile of tumor specimen ALCH-AD0F-TTP1-A (aliquot ALCH-AD0F-TTP1-A-1-0-D-A502-36) from ALCHEMIST case ALCH-AD0F, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma in situ, NOS; Age at diagnosis: 63.9 years (23,330 days).
Specimen ALCH-AD0F-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce6b80c7-7a19-4563-9299-cc5ce5fda2ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AD0F-NB1-A (Blood Derived Normal), aliquot ALCH-AD0F-NB1-A-1-0-D-A502-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03b5a392-f8d6-462d-ba1e-69c0dcd5a012

The open-access MAF lists 26 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Intron 2, Frame Shift Del 2, 5'UTR 2, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG3 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs956136537; called by muse, mutect2
- ATF7IP | c.2710del p.R904Efs*6 | Frame Shift Del (DEL) | VAF 31/293 reads (11%) | catalogued as COSV53765658; called by mutect2, pindel, varscan2
- DNAH9 | c.7169A>T p.Q2390L | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as COSV52334633; called by muse, mutect2
- FFAR3 | c.964C>T p.R322* | Nonsense Mutation (SNP) | VAF 21/323 reads (7%) | catalogued as COSV59909281; called by muse, mutect2
- GRIA4 | c.243C>G p.N81K | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.311); catalogued as COSV99235446; called by muse, mutect2
- KCNMA1 | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 44/679 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as rs564244009, COSV54241021; called by muse, mutect2
- KPRP | c.348G>T p.E116D | Missense Mutation (SNP) | VAF 19/287 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as COSV64222232; called by muse, mutect2
- MYO18B | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1401947638, COSV59144930; called by muse, mutect2, varscan2
- OR52E8 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs207471638; called by muse, mutect2, varscan2
- ACIN1 | c.2263C>T p.H755Y | Missense Mutation (SNP) | VAF 25/367 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.099); called by muse, mutect2
- ANKRD26 | c.3872A>G p.K1291R | Missense Mutation (SNP) | VAF 76/719 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- CDH9 | c.958A>T p.T320S | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.192); called by muse, mutect2
- CRB1 | c.781C>G p.L261V | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.102); called by muse, mutect2
- MCM8 | c.2036del p.P679Qfs*25 | Frame Shift Del (DEL) | VAF 65/478 reads (14%) | called by mutect2, pindel, varscan2
- RBM48 | c.308C>G p.A103G | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WDR17 | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 23/577 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- ZBTB3 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ATP1A2 | c.1566C>A p.G522= | Silent (SNP) | VAF 20/194 reads (10%) | called by muse, mutect2, varscan2
- DBNL | c.543C>T p.A181= | Silent (SNP) | VAF 19/151 reads (13%) | called by muse, mutect2, varscan2
- EEF2K | c.825C>T p.I275= | Silent (SNP) | VAF 18/75 reads (24%) | called by muse, mutect2, varscan2
- RBM25 | c.2343A>G p.E781= | Silent (SNP) | VAF 26/150 reads (17%) | called by muse, mutect2, varscan2
- BBS4 | c.76+2768C>T | Intron (SNP) | VAF 24/416 reads (6%) | called by muse, mutect2
- DIP2B | c.-24C>T | 5'UTR (SNP) | VAF 6/129 reads (5%) | catalogued as rs1361496776; called by muse, mutect2
- SNORD116-22 | chr15:25092083 G>A | 3'Flank (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- SORBS1 | c.2128+1270C>T | Intron (SNP) | VAF 16/114 reads (14%) | catalogued as rs1179921432; called by muse, mutect2, varscan2
- USP30 | c.-42C>T | 5'UTR (SNP) | VAF 3/14 reads (21%) | catalogued as rs1566082355; called by muse, varscan2
